Somatic mutation profile of tumor specimen C3L-08303-03 (aliquot CPT0503820006) from CPTAC case C3L-08303, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.7 years (22,518 days).
Specimen C3L-08303-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a29fc169-82f1-47e4-86e1-ea16ff5cc183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08303-31 (Blood Derived Normal), aliquot CPT0503920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aec457bb-a4ae-4b11-ba4b-656802a7c6b3

The open-access MAF lists 55 somatic variants for this specimen: 49 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 45, Silent 6, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 36/342 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM1 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99521807; called by muse, mutect2
- ADGRV1 | c.13510A>G p.R4504G | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV101316447, COSV67978378; called by muse, mutect2
- DHX16 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 22/683 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs147746362; called by muse, mutect2
- GAL3ST3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1409774009; called by muse, mutect2
- HOXC13 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 50/633 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs759565446, COSV54498442; called by muse, mutect2
- IQANK1 | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 25/715 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs1355695365; called by muse, mutect2
- KLHL1 | c.1130A>T p.H377L | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV64767144; called by muse, mutect2
- NR4A1 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775188977, COSV54483293, COSV54485179; called by muse, mutect2
- NUGGC | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV58434848; called by muse, mutect2
- OR4C16 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 23/587 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV58940425, COSV58941301, COSV58942700; called by muse, mutect2
- PEG3 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs369854592, COSV55632454; called by muse, mutect2, varscan2
- RIMS2 | c.4673T>G p.L1558R (on ENST00000666250 / NM_001348490.2; = p.L1129R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51678593, COSV99154996; called by muse, mutect2
- U2AF2 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs1468001443; called by muse, mutect2
- ABCD1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.061); called by muse, mutect2
- ADGRB3 | c.2933T>G p.L978R | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- AHR | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 14/391 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.565); called by muse, mutect2
- B4GALNT3 | c.708-1G>C p.X236_splice | Splice Site (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
- CAVIN2 | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 30/525 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- CLEC18B | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CNTN1 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- DAPK1 | c.2329T>C p.F777L | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- DGKI | c.2791T>G p.L931V | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- F13A1 | c.1642T>C p.Y548H | Missense Mutation (SNP) | VAF 26/570 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- FANCC | c.512C>G p.T171S | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.11); called by muse, mutect2
- HERC4 | c.1806+1G>T p.X602_splice | Splice Site (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- KLRF2 | c.166T>C p.W56R | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, mutect2
- LNPEP | c.1666_1667del p.L556Vfs*8 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, varscan2
- MEP1B | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.255); called by muse, mutect2
- MRPL38 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2
- NGEF | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 49/520 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NRK | c.3328A>C p.N1110H | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- OR14I1 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 14/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR51T1 | c.469T>G p.F157V | Missense Mutation (SNP) | VAF 20/547 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.176); called by muse, mutect2
- PNN | c.1740T>A p.S580R | Missense Mutation (SNP) | VAF 17/519 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); called by muse, mutect2
- RAC1 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 17/457 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMBP2 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- RIMS1 | c.1949T>A p.L650Q | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO1 | c.1629A>T p.Q543H | Missense Mutation (SNP) | VAF 21/318 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2
- RPE65 | c.21T>A p.H7Q | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RXFP3 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 28/812 reads (3%) | called by muse, mutect2
- RYR2 | c.3308T>G p.F1103C | Missense Mutation (SNP) | VAF 18/493 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SENP6 | c.2356C>T p.H786Y | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.034); called by muse, mutect2
- TAF5 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 29/447 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- TALDO1 | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMDD1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 18/632 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TMPRSS13 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 63/918 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- TTC17 | c.1721T>A p.M574K | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2
- ZNF423 | c.3185C>G p.S1062C (on ENST00000563137 / NM_001379286.1; = p.S1054C on NM_015069.4) | Missense Mutation (SNP) | VAF 17/597 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ABCC12 | c.3096C>T p.L1032= | Silent (SNP) | VAF 15/449 reads (3%) | called by muse, mutect2
- GPR26 | c.417C>T p.A139= | Silent (SNP) | VAF 38/859 reads (4%) | catalogued as rs1359260582, COSV99500829; called by muse, mutect2
- GUCY1A1 | c.1173A>G p.E391= | Silent (SNP) | VAF 21/318 reads (7%) | called by muse, mutect2
- KLHL33 | c.1098T>A p.I366= | Silent (SNP) | VAF 24/800 reads (3%) | called by muse, mutect2
- PCDHB6 | c.555C>T p.S185= | Silent (SNP) | VAF 18/640 reads (3%) | called by muse, mutect2
- THAP11 | c.459C>T p.S153= | Silent (SNP) | VAF 50/672 reads (7%) | catalogued as rs775940118; called by muse, mutect2
